Gene-level copy-number profile of tumor specimen TCGA-08-0389-01A from TCGA case TCGA-08-0389, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,638 days).
Specimen TCGA-08-0389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c77d94eb-9130-4d5f-a01f-477d99a56580.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0389-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e9e539d-dbcc-4a91-8125-dff0d90c919e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 7,809; copy number 2: 48,842; copy number 3: 3,048; copy number 6: 4; copy number 16: 28; copy number 17: 44; copy number 19: 23; copy number 21: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0389-01): tumor purity 0.88, ploidy 1.96, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:165,905,126–166,382,599, 4 genes: AC008489.1, RPL7P20, AC114321.1, AC026403.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 116 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:107,028,199–107,661,306, 7 genes, copy number 17 (within-gene range 1–17): MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP.
- chr6:107,697,299–108,837,113, 36 genes, copy number 17: AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.4, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1.
- chr6:108,856,400–108,856,737, 1 gene, copy number 17: AL445189.1.
- chr6:108,986,437–109,506,800, 16 genes, copy number 6–16: SESN1, AL390208.1, RNU6-653P, CEP57L1, CCDC162P, AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2, PPIL6, SMPD2, MICAL1, ZBTB24, AL109947.1.
- chr6:109,978,256–110,924,107, 23 genes, copy number 19: GPR6, AL590009.1, WASF1, CDC40, METTL24, AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1.
- chr6:111,046,868–111,606,906, 16 genes, copy number 16: GSTM2P1, SLC16A10, RNU6-960P, AL360227.1, MFSD4B, AL080317.1, REV3L, AL080317.2, FCF1P5, REV3L-IT1, BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1.
- chr13:113,276,616–113,816,995, 17 genes, copy number 21: LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B.

Autosomal genes at a single copy (total copy number 1): 5,428. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
